TARGET case TARGET-20-D45-EC-CBFA2T3_GLIS2pool-CD56pos-sort — Acute Myeloid Leukemia (TARGET-AML)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/9e52bb47-e27c-44d7-bdf4-7e8e9b2d5cde

Biospecimens (1 sample)
- Sample TARGET-20-D45-EC-CBFA2T3_GLIS2pool-CD56pos-sort-85: Sample type: Next Generation Cancer Model; Tissue type: Tumor.
